Somatic mutation profile of tumor specimen ALCH-B4AG-TTP1-A (aliquot ALCH-B4AG-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4AG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 59.8 years (21,849 days).
Specimen ALCH-B4AG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d8f8fa2b-3a1a-49fa-b841-e9c8da2067c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4AG-NB1-A (Blood Derived Normal), aliquot ALCH-B4AG-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6de05cab-43bd-44c1-8e6d-1395dff0b181

The open-access MAF lists 272 somatic variants for this specimen: 186 protein-altering or splice-affecting, 51 silent, 35 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 51, Intron 16, Nonsense Mutation 14, RNA 11, Frame Shift Del 5, 5'Flank 4, Splice Site 2, Splice Region 2, In Frame Del 2, 5'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.475G>C p.A159P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs730882000, COSV52661847, COSV52680639, COSV52688008, COSV52782769; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS12 | c.623G>T p.C208F | Missense Mutation (SNP) | VAF 119/289 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as COSV61281804; called by muse, mutect2, varscan2
- AKAP12 | c.4935G>T p.E1645D | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.028); catalogued as COSV53582389; called by muse, mutect2, varscan2
- ALG6 | c.1486G>C p.D496H | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV99585912; called by muse, mutect2, varscan2
- ASTN1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.878); catalogued as COSV99922206; called by muse, varscan2
- CAPRIN1 | c.62C>G p.S21W | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV100404187; called by muse, mutect2, varscan2
- CATSPER1 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV56410907; called by muse, mutect2, varscan2
- CFH | c.1444G>A p.V482I | Missense Mutation (SNP) | VAF 26/268 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.011); catalogued as rs758155649; called by muse, mutect2
- CLPB | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs1388099196, COSV53633058; called by muse, mutect2, varscan2
- COL1A2 | c.3907G>C p.E1303Q | Missense Mutation (SNP) | VAF 52/273 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.934); catalogued as COSV51966141; called by muse, mutect2, varscan2
- COL24A1 | c.306G>C p.L102F | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.217); catalogued as COSV100993779; called by muse, mutect2, varscan2
- COL5A1 | c.3398G>T p.R1133L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65668561; called by muse, mutect2, varscan2
- CREB5 | c.374A>G p.H125R (on ENST00000357727 / NM_182898.4; = p.H118R on NM_004904.3) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs754158273; called by muse, mutect2, varscan2
- CRYBG3 | c.1585C>T p.R529* | Nonsense Mutation (SNP) | VAF 25/229 reads (11%) | catalogued as rs1287069841; called by muse, mutect2, varscan2
- CUBN | c.645C>A p.D215E | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs778456388; called by muse, mutect2, varscan2
- DHX8 | c.1749C>G p.I583M | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV52252914, COSV99292581; called by muse, mutect2
- DLC1 | c.2254G>A p.A752T (on ENST00000276297 / NM_001348081.2; = p.A315T on NM_006094.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.411); catalogued as rs764061122; called by muse, mutect2, varscan2
- FAM161A | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as rs1403374892, COSV56765908; called by muse, mutect2, varscan2
- FBXL4 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 34/168 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs758088733, COSV57749883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLNC | c.7604C>A p.S2535* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as COSV57963512; called by mutect2, varscan2
- FLT1 | c.1583G>A p.R528K | Missense Mutation (SNP) | VAF 47/267 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99163740; called by muse, mutect2, varscan2
- FREM2 | c.6999G>A p.M2333I | Missense Mutation (SNP) | VAF 57/373 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs1229778085; called by muse, mutect2, varscan2
- GRIN2B | c.2956C>T p.H986Y | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); catalogued as COSV74205270; called by muse, mutect2, varscan2
- HECTD4 | c.10646G>A p.S3549N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs747564839; called by muse, mutect2, varscan2
- HERC2 | c.1988G>T p.R663L | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0.107); catalogued as rs765482113, COSV99869875; called by muse, mutect2
- ITFG1 | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs1194659390, COSV100278420; called by muse, mutect2, varscan2
- KCND2 | c.206G>C p.S69T | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV58607945; called by muse, varscan2
- KIF21A | c.3865C>T p.R1289C (on ENST00000361418 / NM_001378440.1; = p.R1276C on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as rs755468804; called by muse, mutect2
- KLHL4 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64142068; called by muse, varscan2
- KLHL40 | c.710G>C p.R237P | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.677); catalogued as COSV55137553; called by muse, varscan2
- LMBRD1 | c.815C>T p.T272M (on ENST00000649011; = p.T250M on NM_018368.4) | Missense Mutation (SNP) | VAF 58/297 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs144613240; called by muse, mutect2, varscan2
- LRP6 | c.4567C>G p.R1523G | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV53784555; called by muse, mutect2, varscan2
- MAN2A1 | c.2672G>A p.R891K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs762478692; called by muse, mutect2, varscan2
- MDGA2 | c.2888T>C p.I963T (on ENST00000399232 / NM_001113498.2; = p.I665T on NM_182830.4) | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV62086582; called by muse, mutect2, varscan2
- ME2 | c.10C>G p.R4G | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.247); catalogued as rs193005055, COSV58422337; called by muse, mutect2, varscan2
- MLXIPL | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs782671517, COSV57670951; called by muse, varscan2
- MTR | c.1816G>C p.G606R | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63964809; called by muse, mutect2
- MYO15A | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs754537525; called by muse, mutect2, varscan2
- NRCAM | c.2812C>A p.P938T (on ENST00000379028 / NM_001371124.1; = p.P922T on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61034057; called by muse, mutect2, varscan2
- PCDHB15 | c.2156C>A p.A719E | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV50870072, COSV51242990; called by muse, mutect2, varscan2
- PDCD11 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs747502502; called by muse, mutect2
- PPP1R3A | c.2473A>T p.M825L | Missense Mutation (SNP) | VAF 54/213 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV52881481; called by muse, mutect2, varscan2
- PRDM9 | c.112del p.E38Kfs*17 | Frame Shift Del (DEL) | VAF 34/247 reads (14%) | catalogued as COSV99691558; called by mutect2, pindel, varscan2
- PRKCQ | c.824C>A p.T275K | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1190085994; called by muse, mutect2, varscan2
- RB1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs868262022, COSV57305952; called by muse, mutect2
- RELN | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 32/445 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.023); catalogued as rs377185504; called by muse, mutect2
- RP1L1 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs559827555; called by muse, mutect2, varscan2
- SAMD9L | c.3511G>C p.D1171H | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as COSV59080488; called by muse, mutect2, varscan2
- SAMSN1 | c.893G>T p.R298L (on ENST00000647101; = p.R70L on NM_001256370.1) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.108); catalogued as rs546183526; called by muse, mutect2, varscan2
- SLC39A6 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 25/135 reads (19%) | catalogued as COSV52368148; called by muse, mutect2, varscan2
- SNTG1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52434501; called by muse, mutect2, varscan2
- STAB2 | c.1395C>A p.F465L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.123); catalogued as rs777860935; called by muse, mutect2
- TRHDE | c.1654G>C p.D552H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV53841174; called by muse, mutect2, varscan2
- TRRAP | c.6244G>T p.D2082Y (on ENST00000359863 / NM_001244580.1; = p.D2064Y on NM_003496.3) | Missense Mutation (SNP) | VAF 34/127 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.188); catalogued as COSV62855985; called by muse, mutect2, varscan2
- TTN | c.66832A>G p.M22278V (on ENST00000591111; = p.M14854V on NM_003319.4) | Missense Mutation (SNP) | VAF 20/66 reads (30%) | PolyPhen benign (0); catalogued as rs777077373; called by muse, mutect2, varscan2
- USP5 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as rs782661613; called by muse, mutect2, varscan2
- XPNPEP1 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV100451198; called by muse, mutect2
- ZBTB16 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV60100126; called by muse, mutect2, varscan2
- ZDBF2 | c.6565G>C p.G2189R | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV100985119; called by muse, mutect2, varscan2
- ABCB7 | c.2228G>T p.S743I (on ENST00000373394 / NM_001271696.3; = p.S744I on NM_004299.6) | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ABLIM3 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- ADGB | c.273A>T p.L91F | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- ADGRG2 | c.2832del p.V945* (on ENST00000379869 / NM_001079858.3; = p.V942* on NM_005756.4) | Frame Shift Del (DEL) | VAF 17/137 reads (12%) | called by mutect2, varscan2
- AK5 | c.308A>T p.Q103L (on ENST00000354567 / NM_174858.3; = p.Q77L on NM_012093.4) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ANKRD12 | c.303A>T p.S101= | Splice Region (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- APOA1 | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- APOA1 | c.253_297del p.R85_L99del | In Frame Del (DEL) | VAF 24/94 reads (26%) | called by mutect2, pindel
- ARHGAP31 | c.2674G>C p.D892H | Missense Mutation (SNP) | VAF 47/222 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ATAD5 | c.3940G>C p.D1314H | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATG14 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2
- BCHE | c.1652C>G p.T551R | Missense Mutation (SNP) | VAF 58/326 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD2 | c.538A>G p.M180V | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- C1R | c.414G>C p.E138D (on ENST00000536053 / NM_001354346.2; = p.E124D on NM_001733.7) | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- C6orf89 | c.737T>G p.F246C (on ENST00000373685; = p.F253C on NM_152734.4) | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CAGE1 | c.2293-1G>C p.X765_splice (on ENST00000512086; = p.X629_splice on NM_205864.3) | Splice Site (SNP) | VAF 11/56 reads (20%) | called by muse, varscan2
- CCDC158 | c.2446-4G>T | Splice Region (SNP) | VAF 31/127 reads (24%) | called by muse, mutect2, varscan2
- CDC42EP4 | c.467A>T p.E156V | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); called by muse, varscan2
- CDKL5 | c.1670C>A p.S557* | Nonsense Mutation (SNP) | VAF 31/271 reads (11%) | called by muse, mutect2, varscan2
- CENPF | c.5175del p.Q1725Hfs*52 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- CFHR4 | c.725A>T p.Y242F (on ENST00000367416 / NM_001201551.2; = p.Y243F on NM_001201550.3) | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CLIP4 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 70/552 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL14A1 | c.2979G>C p.E993D | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CPS1 | c.4243G>T p.G1415* | Nonsense Mutation (SNP) | VAF 51/214 reads (24%) | called by muse, mutect2, varscan2
- CPS1 | c.4244G>T p.G1415V | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CTAGE9 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 60/513 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- CUBN | c.5474G>T p.G1825V | Missense Mutation (SNP) | VAF 55/342 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- CYP2C19 | c.420C>A p.S140R | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- DCX | c.325G>T p.G109* | Nonsense Mutation (SNP) | VAF 40/119 reads (34%) | called by muse, mutect2, varscan2
- DGKK | c.3698G>T p.R1233L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2
- DHX57 | c.3565G>T p.A1189S | Missense Mutation (SNP) | VAF 16/136 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.017); called by mutect2, varscan2
- DNAH8 | c.13010T>A p.I4337K | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- DNAJC22 | c.860G>C p.G287A | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DNTTIP1 | c.950A>C p.E317A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DONSON | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 49/209 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- EEF1A2 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); called by muse, mutect2
- ENPP3 | c.1433G>C p.C478S | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EXOC6B | c.418+1G>C p.X140_splice | Splice Site (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- F5 | c.2756C>A p.S919Y | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- FAM131B | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- FAM71E2 | c.458T>G p.I153S | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- FBXL4 | c.1511G>T p.C504F | Missense Mutation (SNP) | VAF 56/294 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FBXO38 | c.1527C>G p.H509Q | Missense Mutation (SNP) | VAF 43/370 reads (12%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FMN2 | c.1877G>T p.G626V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FMO4 | c.1106G>C p.G369A | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FSTL5 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- GCNA | c.1479C>A p.C493* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2
- GMNC | c.192C>G p.D64E | Missense Mutation (SNP) | VAF 41/164 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPRC5C | c.1386G>C p.Q462H (on ENST00000652232; = p.Q417H on NM_018653.4) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- HNRNPD | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 23/282 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- IGKV2D-29 | c.142del p.S48Afs*25 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by pindel*, varscan2
- IGSF1 | c.1609C>G p.L537V | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IL6ST | c.1093G>C p.D365H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- IQCE | c.1709C>G p.S570* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- IQCK | c.572C>G p.S191C | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ITGA11 | c.1984A>T p.S662C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); called by muse, mutect2
- KBTBD12 | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 30/358 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.141); called by muse, mutect2
- KCNH4 | c.964C>G p.L322V | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KDM5B | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KEL | c.509G>T p.R170I | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by mutect2, varscan2
- KIF13A | c.3265G>C p.E1089Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- KMT2D | c.8550_8592del p.G2851Vfs*45 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel
- KRTAP13-1 | c.354C>A p.Y118* | Nonsense Mutation (SNP) | VAF 20/75 reads (27%) | called by muse, mutect2, varscan2
- LAMA1 | c.4738C>A p.L1580I | Missense Mutation (SNP) | VAF 54/216 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- LAMB2 | c.2212C>G p.L738V | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LINC02210-CRHR1 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.088); called by muse, varscan2
- LPGAT1 | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LRCH2 | c.2069T>C p.V690A | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRP12 | c.403G>A p.D135N | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2
- LY6L | c.101T>G p.F34C | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LY6L | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 2/14 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LYST | c.11228G>T p.R3743I | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAPK13 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MARCHF11 | c.557G>T p.C186F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAST2 | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MDN1 | c.3922G>A p.G1308S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- MTR | c.1817G>T p.G606V | Missense Mutation (SNP) | VAF 36/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- MYH7 | c.990G>A p.M330I | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- N4BP2 | c.88C>G p.R30G | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- NHS | c.3539C>A p.S1180Y | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- OR52J3 | c.621C>G p.F207L | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR8J3 | c.360T>A p.Y120* | Nonsense Mutation (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- OTOG | c.3143C>G p.S1048* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- PALB2 | c.2514G>C p.Q838H | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDH9 | c.1885_1908del p.S629_E636del | In Frame Del (DEL) | VAF 14/151 reads (9%) | called by mutect2, pindel
- PIGS | c.844G>T p.V282L | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PIK3CG | c.2852A>G p.N951S | Missense Mutation (SNP) | VAF 99/242 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PKHD1 | c.10099C>G p.P3367A | Missense Mutation (SNP) | VAF 18/223 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLCH1 | c.4657G>T p.D1553Y (on ENST00000340059 / NM_001130960.2; = p.D1545Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/186 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- PNLIPRP1 | c.549G>C p.K183N | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- POM121L12 | c.103A>T p.R35W | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- PRC1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PRDM4 | c.1745C>G p.P582R | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PRODH2 | c.1109C>A p.A370D (on ENST00000301175; = p.A294D on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- PRRG4 | c.239G>C p.R80T | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PYHIN1 | c.746T>C p.F249S | Missense Mutation (SNP) | VAF 30/249 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- RP1L1 | c.508C>T p.L170F | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- RRBP1 | c.827C>A p.P276Q | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SECISBP2L | c.1129T>C p.S377P | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2
- SGO1 | c.1487G>C p.G496A (on ENST00000263753 / NM_001012410.5; = p.G227A on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHOC2 | c.1164C>G p.D388E | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SI | c.3557G>T p.R1186L | Missense Mutation (SNP) | VAF 64/398 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- SLC52A3 | c.538G>T p.V180L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC9A7 | c.1011G>T p.M337I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.07); called by muse, varscan2
- SORCS1 | c.2003T>G p.I668S | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- SPEG | c.6595C>G p.P2199A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SRPX | c.753C>A p.C251* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | called by muse, varscan2
- STOML1 | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- TAS2R3 | c.527G>C p.S176T | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBC1D15 | c.1691T>C p.L564P | Missense Mutation (SNP) | VAF 15/162 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2
- TENT2 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TMEM185B | c.390C>A p.C130* | Nonsense Mutation (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2, varscan2
- TPCN1 | c.1297G>T p.G433C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TRIM23 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRIM43 | c.266A>C p.E89A | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.39); called by muse, varscan2
- TRIM43 | c.289A>T p.R97W | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- TUBGCP5 | c.2439A>G p.I813M | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2
- UPF1 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- UTP20 | c.7243G>C p.D2415H | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- WDR83OS | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XIRP1 | c.2752A>G p.S918G | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF486 | c.1115A>G p.H372R | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF585B | c.877A>T p.S293C | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2
- ZNF724 | c.1756G>T p.G586* | Nonsense Mutation (SNP) | VAF 36/155 reads (23%) | called by muse, mutect2, varscan2
- ZNF729 | c.2260G>C p.A754P | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ZNF777 | c.142C>G p.P48A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- ZNF8 | c.699C>G p.D233E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AOC3 | c.2115C>G p.L705= | Silent (SNP) | VAF 43/144 reads (30%) | called by muse, mutect2, varscan2
- APBA1 | c.1059C>T p.I353= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV55239291; called by muse, mutect2, varscan2
- ARAP1 | c.2409C>T p.C803= (on ENST00000393609 / NM_001040118.2; = p.C558= on NM_015242.4) | Silent (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- COL12A1 | c.4296G>T p.V1432= | Silent (SNP) | VAF 27/120 reads (23%) | catalogued as COSV59410006; called by muse, mutect2, varscan2
- CSMD3 | c.3597G>T p.G1199= (on ENST00000297405 / NM_001363185.1; = p.G1095= on NM_052900.3) | Silent (SNP) | VAF 239/513 reads (47%) | called by muse, mutect2, varscan2
- CSRNP1 | c.603C>G p.P201= | Silent (SNP) | VAF 18/82 reads (22%) | called by muse, mutect2, varscan2
- DLL4 | c.1122G>A p.G374= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- DNAH5 | c.4512G>T p.G1504= | Silent (SNP) | VAF 50/346 reads (14%) | called by muse, mutect2, varscan2
- DPPA2 | c.246C>A p.A82= | Silent (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- DVL3 | c.2092A>C p.R698= | Silent (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- E2F4 | c.999C>A p.T333= | Silent (SNP) | VAF 24/68 reads (35%) | called by muse, varscan2
- ERBB3 | c.891T>C p.D297= | Silent (SNP) | VAF 50/263 reads (19%) | catalogued as COSV57248891; called by muse, mutect2, varscan2
- FAM20B | c.246A>G p.P82= | Silent (SNP) | VAF 20/119 reads (17%) | called by muse, mutect2, varscan2
- FBXL4 | c.645A>G p.E215= | Silent (SNP) | VAF 26/118 reads (22%) | catalogued as rs752917494; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FOXP2 | c.766C>T p.L256= | Silent (SNP) | VAF 16/168 reads (10%) | catalogued as rs779846813; called by muse, mutect2
- GAS8 | c.1182G>C p.L394= | Silent (SNP) | VAF 10/24 reads (42%) | called by muse, varscan2
- GPR137C | c.393C>T p.P131= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs1480015723; called by muse, mutect2, varscan2
- H1-3 | c.438T>C p.A146= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as rs1176713429; called by muse, mutect2
- HDAC6 | c.3390C>A p.T1130= | Silent (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- HMCN2 | c.4728C>T p.T1576= | Silent (SNP) | VAF 21/39 reads (54%) | called by muse, mutect2, varscan2
- IDH3B | c.228C>T p.V76= | Silent (SNP) | VAF 29/194 reads (15%) | called by muse, mutect2, varscan2
- KMT2D | c.10809G>A p.Q3603= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1555189181, COSV56409836; called by mutect2, varscan2
- LRFN3 | c.348C>T p.G116= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- NBEA | c.5871A>G p.G1957= | Silent (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- NEPRO | c.144C>T p.L48= | Silent (SNP) | VAF 26/242 reads (11%) | catalogued as rs368972518; called by muse, mutect2, varscan2
- NHS | c.2637A>T p.R879= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV66273703; called by muse, mutect2, varscan2
- OR2T12 | c.915G>T p.T305= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV58778078, COSV58779366; called by muse, mutect2, varscan2
- OR8G2P | c.447C>T p.Y149= | Silent (SNP) | VAF 27/167 reads (16%) | called by muse, mutect2, varscan2
- PAX3 | c.1119G>T p.P373= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs149273276; called by muse, mutect2, varscan2
- PBLD | c.520C>T p.L174= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, varscan2
- PIK3C2B | c.2307T>C p.S769= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- PMS1 | c.1383C>T p.S461= | Silent (SNP) | VAF 26/499 reads (5%) | catalogued as rs747621119; called by muse, mutect2
- RPGR | c.462C>T p.A154= | Silent (SNP) | VAF 47/274 reads (17%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.636C>A p.A212= (on ENST00000265814 / NM_001198628.1; = p.A185= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/103 reads (31%) | called by muse, mutect2, varscan2
- SETD4 | c.1026C>T p.L342= | Silent (SNP) | VAF 63/205 reads (31%) | catalogued as rs912977051; called by muse, mutect2, varscan2
- SLC13A2 | c.930A>T p.A310= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2
- SP9 | c.1360C>A p.R454= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- STAB2 | c.2148C>T p.A716= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs1280722297; called by muse, mutect2, varscan2
- SYNM | c.3606G>A p.S1202= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as rs201454977; called by muse, mutect2, varscan2
- TAF1L | c.1134C>A p.G378= | Silent (SNP) | VAF 62/286 reads (22%) | catalogued as rs563249439; called by muse, mutect2, varscan2
- TCP11 | c.351T>C p.I117= (on ENST00000512012; = p.I55= on NM_018679.5) | Silent (SNP) | VAF 23/112 reads (21%) | called by muse, mutect2, varscan2
- TIGIT | c.183G>A p.Q61= | Silent (SNP) | VAF 35/155 reads (23%) | catalogued as rs771137569; called by muse, mutect2, varscan2
- TRABD2A | c.93C>T p.C31= | Silent (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- TRMU | c.1155G>A p.R385= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, varscan2
- UNC13C | c.6564C>A p.L2188= | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- WIPF2 | c.687A>G p.P229= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- ZBTB41 | c.315C>A p.V105= | Silent (SNP) | VAF 18/212 reads (8%) | called by muse, mutect2
- ZNF106 | c.2505G>T p.L835= | Silent (SNP) | VAF 9/126 reads (7%) | called by muse, mutect2
- ZNF76 | c.1266G>T p.A422= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV57355380; called by muse, mutect2, varscan2
- ZNF770 | c.1956A>G p.P652= | Silent (SNP) | VAF 89/293 reads (30%) | called by muse, mutect2, varscan2
- ZNF98 | c.1470C>T p.Y490= | Silent (SNP) | VAF 18/247 reads (7%) | catalogued as COSV100757393; called by muse, mutect2
- ADAMTSL1 | c.2006+1398G>T | Intron (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.2006+1399G>T | Intron (SNP) | VAF 31/152 reads (20%) | called by muse, mutect2, varscan2
- ADGRE4P | n.1607C>T | RNA (SNP) | VAF 6/31 reads (19%) | catalogued as rs111231768; called by muse, mutect2, varscan2
- AICDA | c.428-27C>A | Intron (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2
- AL353804.7 | chrX:73845756 C>G | 5'Flank (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2, varscan2
- ANXA2P2 | n.817C>T | RNA (SNP) | VAF 24/127 reads (19%) | called by muse, mutect2, varscan2
- ATP11AUN | n.772A>T | RNA (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- BIN1 | c.1132-39C>G | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- CAMK2B | c.1597+738G>A | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as rs898967747; called by muse, mutect2, varscan2
- CD164 | c.*532G>C | 3'UTR (SNP) | VAF 7/77 reads (9%) | called by muse, mutect2
- DAO | c.-117G>C | 5'UTR (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
- EPB41L4B | c.1409+1818T>A | Intron (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- FAM90A27P | n.15G>T | RNA (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- FLJ40288 | n.598G>C | RNA (SNP) | VAF 6/69 reads (9%) | called by muse, mutect2
- IGKV2D-28 | chr2:89960754 A>G | 3'Flank (SNP) | VAF 9/30 reads (30%) | called by mutect2, varscan2
- KIAA1958 | c.1172-26817G>T | Intron (SNP) | VAF 13/40 reads (33%) | catalogued as rs1011561329; called by muse, mutect2, varscan2
- LDB3 | c.690-4737C>T | Intron (SNP) | VAF 14/56 reads (25%) | called by mutect2, varscan2
- LINC01619 | chr12:91993260 A>C | 5'Flank (SNP) | VAF 12/97 reads (12%) | called by muse, mutect2, varscan2
- LMO2 | c.-272+710del | Intron (DEL) | VAF 5/24 reads (21%) | called by mutect2, pindel, varscan2
- MIR181B1 | n.95A>T | RNA (SNP) | VAF 35/127 reads (28%) | called by muse, mutect2, varscan2
- MIR557 | n.13T>G | RNA (SNP) | VAF 22/105 reads (21%) | called by muse, mutect2, varscan2
- MLIP | c.613-11800C>T | Intron (SNP) | VAF 23/140 reads (16%) | called by muse, mutect2, varscan2
- NR2F2-AS1 | n.1056C>G | RNA (SNP) | VAF 15/122 reads (12%) | called by muse, mutect2, varscan2
- PQBP1 | c.-131C>A | 5'UTR (SNP) | VAF 14/74 reads (19%) | called by mutect2, varscan2
- PSMC3 | c.75+66G>C | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- PTENP1 | n.1690C>G | RNA (SNP) | VAF 17/341 reads (5%) | called by muse, mutect2
- R3HDM1 | c.2047+4076C>A | Intron (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- RBM34 | chr1:235161320 del CGGCAGTCGGCCGCCGGG | 5'Flank (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel, varscan2
- RPS4XP21 | n.424G>A | RNA (SNP) | VAF 10/53 reads (19%) | catalogued as rs866574886; called by muse, mutect2, varscan2
- RXFP1 | c.1346-454C>A | Intron (SNP) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- SUPT5H | chr19:39441389 G>A | 5'Flank (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- TMEM255B | c.190-933A>C | Intron (SNP) | VAF 8/46 reads (17%) | called by muse, varscan2
- TSBP1-AS1 | n.189C>T | RNA (SNP) | VAF 28/109 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.10360+4576C>G | Intron (SNP) | VAF 30/201 reads (15%) | called by muse, mutect2, varscan2
- UBE2L6 | c.27+532G>T | Intron (SNP) | VAF 20/111 reads (18%) | called by muse, mutect2, varscan2
